Gene-level copy-number profile of specimen HCM-WCMC-0491-C16-85A from HCMI case HCM-WCMC-0491-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 66.0 years (24,110 days).
Specimen HCM-WCMC-0491-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e4779311-31e3-4800-b2c3-873d61f1ea1c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0491-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/373f8489-2485-4c16-bae0-1752209b5dd1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 516; copy number 2: 17,423; copy number 3: 20,300; copy number 4: 15,226; copy number 5: 3,826; copy number 6: 1,263; copy number 7: 57; copy number 8: 20; copy number 9: 10; copy number 10: 36; copy number 11: 20; copy number 23: 15; copy number 24: 11; copy number 28: 110; copy number 35: 6; copy number 38: 35.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 320 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,106,535–11,296,049, 8 genes, copy number 7: MTOR, MTOR-AS1, RNU6-537P, ANGPTL7, RNU6-291P, RPL39P6, UBIAD1, UBE2V2P3.
- chr1:11,479,155–11,674,354, 6 genes, copy number 7: DISP3, AL590989.1, LINC01647, FBXO2, FBXO44, FBXO6.
- chr1:143,498,785–143,500,512, 2 genes, copy number 9: AC239859.2, LINC02799.
- chr1:205,597,556–205,813,748, 8 genes, copy number 7 (within-gene range 3–7): ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, SLC41A1.
- chr2:9,018,293–9,018,899, 1 gene, copy number 8: HMGB1P25.
- chr5:74,111,690–74,536,976, 5 genes, copy number 7: LINC01331, LINC01335, RN7SL814P, LINC01333, LINC01332.
- chr5:138,252,380–138,274,621, 2 genes, copy number 7: GFRA3, RPS27AP18.
- chr8:27,560,274–27,589,073, 1 gene, copy number 7: GULOP.
- chr9:128,068,201–128,204,383, 8 genes, copy number 7 (within-gene range 6–7): SLC25A25, AL360268.1, SLC25A25-AS1, PTGES2, PTGES2-AS1, LCN2, C9orf16, CIZ1.
- chr16:35,207,884–35,284,146, 1 gene, copy number 9 (within-gene range 6–9): AC023824.3.
- chr16:35,245,916–35,879,498, 56 genes, copy number 9–11: FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1.
- chr16:46,469,341–47,464,149, 32 genes, copy number 7–8 (within-gene range 6–8): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA.
- chr17:39,023,394–42,181,142, 190 genes, copy number 7–38 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 516. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
